Surgical pathology report (de-identified scan), TCGA case TCGA-MB-A8JK, project TCGA-SARC (Sarcoma), tissue source site University of Minnesota, specimen TCGA-MB-A8JK-01A (Primary Tumor).

[page 1 of 4]
Date of Tumor Procurement:

SPECIMEN(S):

Right lateral thigh mass

FINAL DIAGNOSIS:

Right lateral thigh mass, resection:

- Undifferentiated pleomorphic sarcoma, Grade 3 out of 3

(differentiation 3 + mitotic index 3 + necrosis 1 = 7/8 by F9d9ration

Nationale des Centres de Lutte Contre le Cancer Grading System)

- Margins: Negative for sarcoma
- Angiolymphatic invasion: Not identified
- See cancer checklist

COMMENT:

Procedure: Radical resection

Tumor Site: Right lateral thigh

Tumor Size: 3.9 x 3.0 x 2.7 cm

Macroscopic Extent of Tumor: Deep

Fascial and subfascial

Histologic Type (World Health Organization [WHO] classification of soft

ICD-O-3
Sarcoma, pleomorphic cell, undifferentiated
(8802/3) (8805/3)
Code to highest 8805/3
Site: Thigh NOS C49.2
y. 11/27/14

[page 2 of 4]
tissue tumors):

Undifferentiated pleomorphic sarcoma

Mitotic Rate: 3

Specify: > 20 /10 high-power fields (HPF) Necrosis (macroscopic or microscopic): Present

Extent: < 5%

Histologic Grade (French Federation of Cancer Centers Sarcoma Group [FNCLCC]): Grade 3

Margins: Negative for sarcoma. Distance of sarcoma from closest anterior margin: 0.3 cm

Lymph-Vascular Invasion: Not identified

Lymph Nodes:

Number Examined: 0

Number Involved: 0

Ancillary Studies: Not

Preresection Treatment: Unknown

Treatment Effect: Not identified

Distant Metastasis (pM): Not applicable

Pathologic Staging (pTNM): pT1b Nx Mx

The pathologic stage assigned here should be regarded as provisional, as it reflects only current pathologic data and does not incorporate full knowledge of the patient's clinical status and/or prior pathology.

I have personally reviewed all specimens and or slides, including the

[page 3 of 4]
listed special stains, and used them with my medical judgement to determine the final diagnosis.

CLINICAL HISTORY:

The patient is a year-old male with right knee sarcoma.

GROSS:

One formalin-filled container is received labeled with the patient's name, and medical record number.

The container is labeled "right lateral thigh mass." The specimen consists of an 8.3 x 4.2 x 3.6 cm, 70.0 gm mixed dark red and yellow-tan soft tissue fragment. The attached ellipse of skin measuring 8.3 x 3.8 cm shows a 2.6 cm well-healed incision scar. The specimen is oriented as follows: Long double stitch at 12:00 - proximal margin, single stitch at 3:00 - anterior margin. The resection margins are inked as follows: Anterior margin - orange, posterior margin - blue, deep margin - black. Sectioning along the long axis of the specimen demonstrates a 3.9 x 3.0 x 2.7 cm, circumscribed pink-tan soft tissue mass with focal area of organizing hemorrhage suggestive of previous biopsy site. The tumor is 2.2 cm from the proximal resection margin, 2.1 cm from the distal resection margin, 0.6 cm from the anterior margin, 0.3 cm from the posterior margin, and 2.2 cm from the deep resection margin.

Representative tissue was procured for potential future studies.

Representative sections are submitted in twelve cassettes.

[page 4 of 4]
Summary of sections:

- 1 - proximal margin, perpendicular.
- 2 - distal margin, perpendicular.
- 3 - anterior margin, perpendicular.
- 4 - posterior margin, perpendicular.
- 5 - deep margin.
- 6 through 12 - tumor.

MICROSCOPIC:

Microscopic evaluation is performed.

Source: NCI Genomic Data Commons file c6d45be7-b879-45aa-a5a1-245375f27e59 (TCGA-MB-A8JK.E691C6A1-9B89-415B-B47C-E98546C52436.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).